Surgical pathology report (de-identified scan), TCGA case TCGA-UZ-A9PS, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UZ-A9PS-01A (Primary Tumor).

[page 1 of 2]
1st Primary.

2nd Primary sent at same time

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]

Med. Rec. #: [REDACTED]

DOB: [REDACTED]

Soc. Sec. #: [REDACTED]

Physician(s): [REDACTED]

Visit #: [REDACTED]

Sex: [REDACTED]

Location: [REDACTED]

Accession #: [REDACTED]

Service Date: [REDACTED]

Received: [REDACTED]

Client: [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

Left kidney, partial nephrectomy: Papillary renal cell carcinoma, Type 2, Furhman Grade 3, 13.2 cm; see comment.

COMMENT:

Kidney Tumor Synoptic Comment

- Histologic type: Papillary type.
- Grade: Furhman grading for RCC: Grade 3.
- Maximum tumor diameter: 13.2 cm.
- Site within kidney: Left lower pole.
- Renal pelvis: Not present.
- Ureter: Not present.
- Renal sinus: Not present.
- Hilar renal veins: Not present.
- Intrarenal veins and lymphatics: Normal, no vascular invasion identified.
- Adrenal gland: Not present.
- Capsule/perirenal fat: Tumor does not penetrate capsule.
- Hilar lymph nodes (number positive/number of nodes): Not present.
- Resection margins: Negative.
- Proximity to nearest margin: 1 mm to resection margin (Slide A1).
- Stage: pT2NXMX.

-Additional comments: This is a typical papillary renal cell carcinoma with a papillary growth pattern and stromal foam cells. Various cell types are present including chromophilic cells with eosinophilic cytoplasm, oxyphilic cells, and occasional clear cells. The relatively large tumor cell size, nuclear atypia, and pleomorphism indicate that this is a type 2 papillary cancer, which in some studies has been an adverse finding relative to type 1. The excision margin is free of tumor, although tumor approaches to within 1 mm of the inked edge of the specimen (slide A1).

ICD-O-3
Carcinoma, papillary renal
cell 8260/3
Site @ Kidney NOS C64.9
JW 3/30/14

Pw TSS, 0% clear cell differentiation.

Specimen(s) Received

A: Left renal mass (fresh)

[page 2 of 2]
Clinical History

The patient is a [REDACTED]-year-old female with a 5 cm, solid mass in the lateral portion of the right kidney and a 9 cm mass in the lower portion of the left kidney. The patient now undergoes left partial nephrectomy.

Gross Description

The specimen is received fresh in one part, labeled with the patient's name, medical record number and "left renal mass fresh," and consists of an unoriented partial nephrectomy specimen measuring 17 x 7.5 x 14.5 cm and weighing 468 gm with associated perinephric fat. There is a yellow-red, nodular, friable mass measuring 8.5 x 6.2 x 13.2 cm, completely filling and obliterating the inner portion of the kidney. The mass is completely circumscribed by the renal capsule and abuts its surface in multiple areas, but does not grossly extend through it. The mass abuts the resection margin (inked blue). The entire outer portion of the specimen is inked in black. The mass was opened prior to receipt in Pathology, and a piece of the tumor was sampled from the previously opened area for [REDACTED]. In addition, an opposite end was opened to sample for normal renal tissue, but none was taken, as it was a completely obliterative tumor. Representative sections are submitted as follows:

Cassettes A1-A2: Tumor with adjacent resection margin.

Cassettes A3-A6: Tumor and renal capsule.

Cassettes A7-A9:

Tumor.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[REDACTED] Pathology Resident

[REDACTED] Pathologist

Electronically signed out on [REDACTED]

1st Primary
(2nd Primary sent at same time.)

Source: NCI Genomic Data Commons file 06f99d01-aba7-409a-879f-2c260762ae53 (TCGA-UZ-A9PS.EA2ECCDC-A411-4926-A8E7-7375F329A687.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).